Gene-level copy-number profile of tumor specimen TCGA-77-A5G3-01A from TCGA case TCGA-77-A5G3, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.4 years (23,171 days).
Specimen TCGA-77-A5G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.852717de-a117-437a-994e-661891a0f679.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5G3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b427bfc5-9eb4-4ae5-aeac-8765a0ee2f79

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,849; copy number 3: 9,561; copy number 4: 22,748; copy number 5: 9,800; copy number 6: 3,700; copy number 7: 1,270; copy number 8: 567; copy number 9: 1,145; copy number 10: 893; copy number 11: 23; copy number 12: 27; copy number 16: 175; copy number 26: 19; copy number 34: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-A5G3-01A-31D-A27J-01): tumor purity 0.65, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,318 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,494,329–121,580,524, 5 genes, copy number 9: AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr2:46,899,275–49,888,986, 53 genes, copy number 10: AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75.
- chr2:50,324,643–50,345,598, 1 gene, copy number 10: AC068725.1.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 9–12 (broad region; genes not listed).
- chr4:51,843,000–54,295,272, 43 genes, copy number 10 (within-gene range 7–10): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1.
- chr4:67,701,209–68,080,952, 1 gene, copy number 10 (within-gene range 5–10): UBA6-AS1.
- chr4:67,766,480–71,804,041, 108 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr6:65,302,522–66,094,909, 4 genes, copy number 9: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:77,650,274–77,927,028, 1 gene, copy number 10 (within-gene range 4–10): MEI4.
- chr9:34,521,043–34,774,466, 20 genes, copy number 10: ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A.
- chr9:34,832,295–34,838,586, 1 gene, copy number 10: FAM205BP.
- chr11:68,612,899–69,494,952, 28 genes, copy number 10: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488.
- chr13:72,586,680–73,661,891, 18 genes, copy number 11: AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:73,800,074–73,802,203, 1 gene, copy number 11: AL138713.1.
- chr18:25,061,924–25,352,190, 4 genes, copy number 11 (within-gene range 8–11): ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr22:20,424,584–23,008,356, 230 genes, copy number 16–34 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
